TCGA case TCGA-72-4232 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: NCH.
https://portal.gdc.cancer.gov/cases/45f6d94b-6f45-4890-a418-0f891b3d9e12

Biospecimens (1 sample)
- Sample TCGA-72-4232-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.6; Intermediate dimension: 0.5; Shortest dimension: 0.1.
